Surgical pathology report (de-identified scan), TCGA case TCGA-QB-AA9O, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Emory University, specimen TCGA-QB-AA9O-06A (Metastatic).

[page 1 of 4]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited. regarding

Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

7AD-0.3
Melanoma NOS 8720/3
Site: Subcutaneous tissue, arm
(049.1)
JW 11/7/14

Patient Name:
MRN:
Location:
Client:
Submitting
Phys:

DOB:
Gender: M

Acc #:
(Age:)
Collected:
Received:
Reported:

Final Surgical Pathology Report

*** ADDENDUM PRESENT ***

Addendum Diagnosis

Skin and subcutaneous tissue, right epitrochlear, *BRAF* analysis (block C7; performed by

- NEGATIVE for the *BRAF* V600E mutation.

For the complete report from
the
was performed by

Services, please refer to the "Outside Labs" section of the lab result flowsheet in
This test was performed using the *BRAF* V600 Mutation Test. This analysis
and was not performed at

The results are being reported here for convenience and as supplemental information only.

The final diagnosis as reported below remains unchanged.

Electronically Signed by

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Final Pathologic Diagnosis

- A. LYMPH NODES, RIGHT AXILLA, LEVELS 1 AND 2, LYMPHADENECTOMY:
- METASTATIC MELANOMA PRESENT IN FOUR OF THIRTEEN LYMPH NODES (4/13).
- EXTRACAPSULAR EXTENSION: NOT IDENTIFIED ON REPRESENTATIVE CROSS SECTIONS.
- B. LYMPH NODES, RIGHT AXILLA, LEVELS 2 AND 3, LYMPHADENECTOMY:
- METASTATIC MELANOMA PRESENT IN THREE OF FOUR LYMPH NODES (3/4).
- EXTRACAPSULAR EXTENSION: NOT IDENTIFIED ON REPRESENTATIVE CROSS SECTIONS.
- C. SKIN AND SUBCUTANEOUS TISSUE, RIGHT EPITROCHLEAR, EXCISION:
- METASTATIC MELANOMA (7.6 X 6.6 X 4.9 CM).
- TUMOR PRESENT WITHIN 0.1 MM OF DEEP SURGICAL MARGIN.

SEE COMMENT

Comment

The right epitrochlear melanoma is based in the subcutis but extends to the overlying ulcerated skin surface. No intraepidermal component is seen in the adjacent intact epidermis.

The largest lymph node with metastatic melanoma grossly measures 6.0 cm.

The tumor shows strong diffuse positive staining for melan A and MITF. Although there is also patchy staining for AE1/3, the immunofindings in conjunction with the morphologic appearance support the diagnosis (immunostains performed on specimens A and C).

Electronically Signed by

Assisted by:

Addendum / Signed Out

Clinical History

Excision of right upper extremity metastatic melanoma and right axillary dissection.

Specimen(s) Received

- A: Right axillary contents, levels 1 and 2
- B: Right axillary contents, levels 2 and 3
- C: Right epitrochlear mass with epitrochlear contents

Gross Description

All three specimens are received fresh, labeled with the patient's name and medical record number.

Specimen A is further designated as "right axillary contents, levels 1 and 2." It consists of an ellipse of white skin measuring 15.0

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

x 3.0 cm and excised to a depth of 15.0 cm. The skin is grossly unremarkable. Multiple lymph nodes and possible tumor nodules are identified within the specimen ranging in size from 1.0 to 6.0 cm in greatest dimension. The lymph nodes are submitted as follows. (Dictated by

Specimen B is further designated "right axillary contents, levels 2 and 3." The specimen consists of fatty tissue, four lymph nodes ranging in size from 0.5 x 0.4 x 0.4 cm to 3.2 x 2.6 x 1.3 cm. The largest node appears grossly positive. Representative sections are submitted as follows. (Dictated by

Specimen C is received fresh in a container labeled with the patient's name, medical record number and "right epitrochlear mass with epitrochlear contents." The specimen consists of an unoriented portion of skin and underlying subcutaneous tissue measuring 13.0 x 8.4 cm and excised to a depth of 2.9 cm. Located on the skin surface is a fungating lobular mass measuring 7.6 x 6.6 x 4.9 cm and is less than 1.0 mm from the surgical excision margin. The cut surface of the tumor is lobulated and yellow-white with areas of necrosis. A portion of tissue is submitted for Tissue Bank. The surgical excision margin is inked black. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

A1:	One lymph node, bisected
A2:	One lymph node, bisected
A3:	Representative section of grossly positive lymph node
A4:	One lymph node, bisected
A5:	One lymph node, bisected
A6:	Two lymph nodes, whole
A7:	Two lymph nodes, whole
A8:	One lymph node, bisected
A9:	One lymph node, bisected
A10:	Representative section grossly positive lymph node, 3.0 cm in greatest dimension
A11:	Representative section of grossly positive lymph node, 5.0 cm in greatest dimension
A12:	Representative section of tumor nodule, 6.0 cm in greatest dimension
B1,2:	Representative sections of grossly positive lymph node
B3:	Lymph node, trisected
B4:	Lymph node, trisected
B5:	One whole lymph node
C1:	Tumor at closest approach to margin
C2-8:	Representative sections of tumor
C9:	Representative in uninvolved tissue

Microscopic Description

Microscopic examination is performed.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 3beb68e3-4a89-469d-b502-822f68214430 (TCGA-QB-AA9O.29D0A7CE-8D23-4433-B857-8348A03475C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).